Somatic mutation profile of tumor specimen BA2998D (aliquot aq-BA2998D) from BEATAML1.0 case 2512, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Refractory anemia with excess blasts; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.5 years (23,180 days).
Specimen BA2998D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e631307-4261-4c11-a343-1c5ee921c7ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2793D (Solid Tissue Normal), aliquot aq-BA2793D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ba9235b-094f-4bf2-8f5d-8a2c2fb8fa9a

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPX6 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV62659091; called by muse, mutect2
- AMOT | c.1537G>T p.E513* (on ENST00000371959 / NM_001113490.1; = p.E104* on NM_133265.3) | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- COX6A2 | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- FAM124B | c.9G>T p.E3D | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.062); called by muse, mutect2
- HMGCS1 | c.732G>T p.W244C | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); called by muse, mutect2
- JAKMIP3 | c.523G>T p.V175L | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.107); called by muse, mutect2
